Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1D7, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1D7-01A (Primary Tumor).

ICD-0-3

Adenocarcinoma, mucinous, Nos 8480/3

Site Code: Sigmoid colon, C18.7

1/10/11 *lw*

(First Tumor)

Tumor Site:	Sigmoid Distal		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☐ No	☐ Yes	☒ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	Lymphoid Aggregates		
Crohn's like reaction	☐ None	☒ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☐ Expansile	☒ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	4		
Pathologist Comment:			

HIFAA Discrepancy		☒

Source: NCI Genomic Data Commons file e7a1a3a5-a608-4dc1-923c-dc4595c894ac (TCGA-DM-A1D7.73512C13-D2EB-4E6C-9A26-3759252F385A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).